Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABLL, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABLL-TTP1-B (Primary Tumor).

[page 1 of 2]
1CB-0-3

adenocarcinoma, with mixed subtypes 8255/3
Site: (R) lung, upper lobe C34.1

1CB-10
C34.11

hw
3/10/10

Material: 1. Bronchus at section level, Extemporaneous 2. Lymph node N.11 3. Lymph node N.10 4. Lymph node N.10 5. Lymph node N.11 6. Lymph node N.8 7. Lymph node N.7 8. Lymph node N.11 9. Lymph node N.4 10. Lymph node N.4 11. Lymph node N.4 12. Lymph node adhering to upper cava. 13. Lymph node N.2 14. Lymph node N.4 15. Fat 16. Upper right lobe 17. Tumor infiltrating cava 18. Lymph node N9

Macro Description: 1. 0.4 cm fragment. The sample was included and entirely examined. Extemporaneous diagnosis (E04/32): negative. 2. 0.5 cm nodule. The sample was included and entirely examined. 3. 0.9 cm nodule. The sample was included and entirely examined. 4. 0.6 cm nodule. The sample was included and entirely examined. 5. Two fragments, the larger 0.7 cm. The sample was included and entirely examined. 6. Multiple fragments, the largest 0.7 cm, The sample was included and entirely examined. 7. 1.1 cm nodule. The sample was included and entirely examined. 8. Four fragments, the largest 0.7 cm. The sample was included and entirely examined. 9. 1.6 cm nodule. The sample was included and entirely examined. 10. 0.4 cm nodule. The sample was included and entirely examined. 11. 0.4 cm nodule. The sample was included and entirely examined. 12. 1.2 cm nodule and a small fragment. The sample was included and entirely examined. 13. Multiple fragments, the largest 1.6 cm. The sample was included and entirely examined. 14. Multiple fragments, the largest 0.6 cm. The sample was included and entirely examined. 15. 2.6 cm fragment including grayish-white nodular areas. 16. 13x9x5 cm lung lobe that when cut shows in the central site, a hard, grayish, 5x4.5 cm, voluminous neoformation with the central area excavated and colliquated. Pleura does not appear infiltrated. 17. 3x2 cm nodule, when cut, constituted of grayish tissue. 18. Two nodular fragments, the larger 0.7 cm. The sample was included and entirely examined.

Micro Description: 1. 2. 3. 4. 5. 6. 7. 8. 9. 10. 11. 12. 13. 14. 15. 16. 17. 18.

Moderately differentiated adenocarcinoma of the solid, acinar, papillary, bronchioalveolar type. Necrosis, mitoses, intratumoral vascular invasion, focal infiltration of the visceral pleura are observed. Neoplasia is amply present in caval sub-azygos fat of sample n. 15 and in the nodule of sample n. 17 where a fragment of the vascular wall, amply infiltrated and focally surpassed by proliferation, is recognizable.

Bronchial margin sent during the operation, negative for neoplasia. Non neoplastic parenchyma: peritumoral post-obstructive pneumonia, endoalveolar macrophages with smoke-correlative pigment and aspects of respiratory bronchiolitis and emphysema in the remaining parenchyma. Lymph nodes: massive lymphnodal and extra-lymphnodal metastasis observed in lymph node n. 4 (sample n. 9), lymph node adhering to upper cava (sample n. 12) and lymph node n. 2 (sample n. 13); extra-lymphnodal neoplastic foci are moreover present in lymph node n. 4 of sample n. 14. All the other lymph nodes examined show non-specific reactive modifications.

Conclusions and histopathological diagnosis:

1. Bronchial margin negative for neoplasia.
2. 3. 4. 5. 6. 7. 8. 10. 11. 18. reactive lymph nodes, negative for metastasis.
9. 12. 13. Massive lymphnodal and extralymphnodal metastasis of poorly differentiated adenocarcinoma.
14. Foci of poorly differentiated adenocarcinoma in perilymphnodal adipose tissue.
15. 17., Infiltration of poorly differentiated adenocarcinoma.

[page 2 of 2]
16. Moderately differentiated adenocarcinoma of the mixed type.

Stage: -

Report 2:

Date Report 2:

Material 2:

Macro Description 2:

Notes:

ICDO Code: 82553

ICDO Description: Adenocarcinoma with mixed subtypes

Status: OK

Other Info:

Source: NCI Genomic Data Commons file 3b22cfcb-6f5e-4419-bf53-7a7f43609c75 (CDDP-ABLL-TTP1.B754B9A5-034A-48F9-84F0-1656BDB202F9.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).